Somatic mutation profile of cancer-model specimen HCM-SANG-0292-C15-85A (3D Organoid; aliquot HCM-SANG-0292-C15-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0292-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0292-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 521b8ce4-5f0d-4cff-826a-a8cea7f2c83f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0292-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0292-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de1a82c6-fe2f-4a4f-8e80-5d29be8185fc

The open-access MAF lists 229 somatic variants for this specimen: 176 protein-altering or splice-affecting, 47 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 47, Nonsense Mutation 5, Frame Shift Del 4, 3'UTR 3, Intron 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 500/501 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM10 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs200220902, COSV99546527; called by muse, mutect2, varscan2
- AP2A1 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 100/479 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1437761857; called by muse, mutect2, varscan2
- ARHGAP44 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1337602328, COSV99310704; called by muse, mutect2, varscan2
- ARID1A | c.5047G>T p.E1683* | Nonsense Mutation (SNP) | VAF 134/398 reads (34%) | catalogued as COSV61374206, COSV61374289; called by muse, varscan2
- ASCL1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 210/786 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57151569; called by muse, mutect2, varscan2
- BACH1 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 110/111 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs776444258; called by muse, mutect2, varscan2
- C5orf52 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 68/441 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV69625878; called by muse, mutect2, varscan2
- CACNA2D3 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs759521794, COSV99873352; called by muse, mutect2, varscan2
- CCDC180 | c.4916A>C p.Q1639P | Missense Mutation (SNP) | VAF 115/439 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV63829154; called by muse, mutect2, varscan2
- CD163 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 225/371 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs752244536; called by muse, mutect2, varscan2
- CDH9 | c.2063T>G p.L688R | Missense Mutation (SNP) | VAF 217/454 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV50251341; called by muse, mutect2, varscan2
- CFAP94 | c.431A>G p.K144R (on ENST00000320267 / NM_001352064.2; = p.K150R on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/1564 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1306150552; called by muse, mutect2
- CHIT1 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 506/507 reads (100%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as rs374021722; ClinVar: uncertain significance; called by muse, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- COL21A1 | c.334G>T p.G112* | Nonsense Mutation (SNP) | VAF 143/428 reads (33%) | catalogued as COSV55167355; called by muse, mutect2, varscan2
- CUX2 | c.2546C>T p.T849M | Missense Mutation (SNP) | VAF 226/887 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1486606771, COSV99921275; called by muse, varscan2
- DDX4 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 181/306 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs1343414629; called by muse, mutect2, varscan2
- DDX51 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 260/1025 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as rs375550193; called by muse, mutect2, varscan2
- DGKZ | c.1535G>T p.R512L (on ENST00000454345 / NM_001105540.2; = p.R324L on NM_003646.4) | Missense Mutation (SNP) | VAF 268/397 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58991960; called by muse, mutect2, varscan2
- DLGAP2 | c.62A>G p.D21G | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1056632804; called by muse, mutect2
- DOCK4 | c.5576C>T p.T1859M | Missense Mutation (SNP) | VAF 551/1076 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs781493990; called by muse, mutect2, varscan2
- E2F8 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 130/559 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs1189697168; called by muse, mutect2, varscan2
- EFEMP1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs759260191; called by muse, mutect2, varscan2
- EGR4 | c.1612G>A p.E538K (on ENST00000545030; = p.E435K on NM_001965.4) | Missense Mutation (SNP) | VAF 192/544 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71532053; called by muse, mutect2, varscan2
- EHD2 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 337/483 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs149479756, COSV54408187; called by muse, mutect2, varscan2
- EIF5B | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 138/246 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as rs997133928; called by muse, mutect2, varscan2
- EYS | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 391/391 reads (100%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.03); catalogued as COSV60998343; called by muse, mutect2, varscan2
- FAAP100 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 213/657 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs371108104; called by muse, mutect2, varscan2
- FAM234B | c.236C>A p.T79K | Missense Mutation (SNP) | VAF 199/642 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.056); catalogued as rs763811520; called by muse, mutect2, varscan2
- FAM53A | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 170/504 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs779534648; called by muse, varscan2
- FAXDC2 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 458/611 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs755057180, COSV100303947; called by muse, mutect2, varscan2
- FGFR2 | c.1975A>C p.K659Q | Missense Mutation (SNP) | VAF 129/194 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60638890; called by muse, mutect2, varscan2
- FOXB2 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 236/690 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.662); catalogued as rs1162244946; called by mutect2, varscan2
- GDF7 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 195/545 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55347575; called by muse, mutect2, varscan2
- GPR137 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 301/452 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as rs979585557, COSV57402767; called by muse, mutect2, varscan2
- H2AC1 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 98/354 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51237038; called by muse, mutect2, varscan2
- H3C12 | c.333_334del p.A112Yfs*11 | Frame Shift Del (DEL) | VAF 310/504 reads (62%) | catalogued as rs763163035; called by pindel, varscan2
- HEXA | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 267/268 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745432499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIVEP3 | c.2537A>C p.K846T | Missense Mutation (SNP) | VAF 271/392 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV56010537; called by muse, mutect2, varscan2
- HMCN1 | c.5807A>G p.N1936S | Missense Mutation (SNP) | VAF 598/598 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs764316876; called by muse, mutect2, varscan2
- HRNR | c.3176A>G p.Q1059R | Missense Mutation (SNP) | VAF 635/766 reads (83%) | SIFT tolerated (0.12); PolyPhen benign (0.356); catalogued as COSV64256097; called by muse, mutect2, varscan2
- HSF1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 193/385 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as rs917029296; called by muse, mutect2, varscan2
- KCNA6 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 215/216 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54974157; called by muse, mutect2, varscan2
- LRP1B | c.334C>G p.H112D | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV67196292; called by muse, mutect2, varscan2
- LRRC4B | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 305/1204 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs202218788, COSV65350563; called by muse, mutect2
- MAP2K3 | c.128A>C p.N43T (on ENST00000342679 / NM_145109.3; = p.N14T on NM_002756.4) | Missense Mutation (SNP) | VAF 214/536 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV57577835; called by muse, mutect2
- MITF | c.1030G>A p.G344R (on ENST00000448226 / NM_006722.3; = p.G244R on NM_000248.4) | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58833693; called by muse, mutect2, varscan2
- MKNK2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 296/451 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1338368906; called by muse, mutect2, varscan2
- MMD2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 439/1122 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.396); catalogued as rs749395200, COSV101286891; called by muse, mutect2, varscan2
- MPND | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 276/521 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs555051709; called by muse, mutect2
- MUC17 | c.6338C>T p.P2113L | Missense Mutation (SNP) | VAF 154/960 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as rs192070108; called by muse, mutect2, varscan2
- NAV3 | c.6928G>C p.A2310P (on ENST00000397909 / NM_001024383.2; = p.A2288P on NM_014903.6) | Missense Mutation (SNP) | VAF 121/548 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1029311922, COSV57094754; called by muse, mutect2, varscan2
- NCOA1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 287/470 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56052179; called by muse, mutect2, varscan2
- NEB | c.7135G>A p.V2379M | Missense Mutation (SNP) | VAF 119/428 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs762314316; called by muse, mutect2, varscan2
- OPA1 | c.2288G>A p.S763N (on ENST00000361510 / NM_130837.3; = p.S708N on NM_015560.3) | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs1429789663, COSV62481880; called by muse, mutect2, varscan2
- OR2F1 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 156/713 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV67330804; called by muse, mutect2, varscan2
- PAPPA | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 380/715 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1023213977; called by muse, mutect2, varscan2
- PCDHB15 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 158/763 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782718695, COSV51147261; called by muse, mutect2, varscan2
- PCDHB5 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 196/1005 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.031); catalogued as COSV50647805; called by muse, mutect2, varscan2
- PCDHGA7 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 132/829 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV99545716; called by muse, mutect2, varscan2
- PDE1C | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 125/755 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1330510855, COSV58525565; called by muse, mutect2, varscan2
- PIK3R5 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 438/438 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs780653156; called by muse, mutect2, varscan2
- PLCL1 | c.2205G>T p.K735N | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70820903; called by muse, mutect2, varscan2
- PRAG1 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 141/310 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58167716; called by muse, mutect2, varscan2
- PRR16 | c.288A>C p.K96N (on ENST00000407149 / NM_001300783.2; = p.K73N on NM_016644.2) | Missense Mutation (SNP) | VAF 165/448 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs1253556021, COSV101088492; called by muse, mutect2, varscan2
- PRUNE2 | c.2772G>T p.E924D | Missense Mutation (SNP) | VAF 331/461 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100944229; called by muse, mutect2, varscan2
- PTCHD3 | c.1691A>C p.K564T | Missense Mutation (SNP) | VAF 165/530 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV71257311; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.302); catalogued as rs201430480, COSV51488527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF1 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 125/535 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs369085148; called by muse, mutect2, varscan2
- RELN | c.2726C>G p.A909G | Missense Mutation (SNP) | VAF 261/560 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.061); catalogued as COSV100632849; called by muse, mutect2, varscan2
- ROBO3 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 276/456 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs745483542, COSV67299485; called by muse, mutect2, varscan2
- RYR1 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 107/472 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757399861, COSV62100636, COSV62112455; ClinVar: uncertain significance; called by muse, mutect2
- SCGN | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58545798; called by muse, mutect2, varscan2
- SCIN | c.1145C>T p.P382L (on ENST00000297029 / NM_001112706.3; = p.P135L on NM_033128.3) | Missense Mutation (SNP) | VAF 210/740 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs372057101; called by muse, mutect2, varscan2
- SPTBN4 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 209/826 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs1230696589; called by muse, mutect2, varscan2
- SSH1 | c.3106G>A p.A1036T | Missense Mutation (SNP) | VAF 129/579 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs575424530, COSV58456145; called by muse, mutect2, varscan2
- SYCP1 | c.1535A>C p.K512T | Missense Mutation (SNP) | VAF 78/142 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65695330, COSV65696539; called by muse, mutect2, varscan2
- TCERG1L | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 139/430 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369422870; called by muse, mutect2, varscan2
- TLL1 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1292152415, COSV50263487, COSV50268157; called by muse, mutect2, varscan2
- TMEM132B | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 144/511 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as rs372738030, COSV100170826; called by muse, mutect2, varscan2
- TMEM94 | c.2280_2281del p.Q761Afs*41 | Frame Shift Del (DEL) | VAF 323/691 reads (47%) | catalogued as rs1439176233; called by pindel, varscan2
- TNXB | c.8530C>T p.R2844W (on ENST00000647633; = p.R2597W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 412/412 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs776540292; called by muse, mutect2, varscan2
- TSHZ1 | c.1439C>A p.A480D (on ENST00000580243 / NM_001308210.2; = p.A435D on NM_005786.6) | Missense Mutation (SNP) | VAF 286/425 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV100433420; called by muse, mutect2, varscan2
- ZNF117 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 229/463 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV51429453; called by muse, mutect2, varscan2
- ZNF729 | c.2157A>C p.K719N | Missense Mutation (SNP) | VAF 173/291 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747393908, COSV100675789; called by muse, mutect2, varscan2
- ACOT12 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- AKR1C1 | c.499A>T p.N167Y | Missense Mutation (SNP) | VAF 133/446 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASAP2 | c.1064A>G p.Q355R | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ASXL3 | c.4979T>C p.L1660P | Missense Mutation (SNP) | VAF 105/105 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BAAT | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 48/700 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- BARHL1 | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 176/849 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- C19orf81 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 701/921 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CA3 | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 98/479 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CASQ2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 127/263 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CCDC168 | c.17750T>G p.L5917R | Missense Mutation (SNP) | VAF 219/459 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC168 | c.15200T>A p.V5067D | Missense Mutation (SNP) | VAF 151/324 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCR5 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK13 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 714/1456 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, varscan2
- COL6A3 | c.1020C>A p.S340R | Missense Mutation (SNP) | VAF 167/381 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DIPK2A | c.1036T>G p.S346A | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DLX6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 512/1052 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP10 | c.2379A>C p.E793D | Missense Mutation (SNP) | VAF 109/164 reads (66%) | SIFT tolerated (0.57); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EIF4B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 256/754 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ELAC1 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 99/273 reads (36%) | called by mutect2, varscan2
- ESR2 | c.922C>A p.H308N | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- EVA1A | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 212/625 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- F8A1 | c.1054_1055insTTT p.Q352delinsL* | Nonsense Mutation (INS) | VAF 130/229 reads (57%) | called by mutect2, pindel, varscan2
- FAM160B1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 233/350 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM184B | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 146/444 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FAT3 | c.4103A>C p.N1368T | Missense Mutation (SNP) | VAF 268/389 reads (69%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FBXO32 | c.197A>T p.K66M | Missense Mutation (SNP) | VAF 442/591 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FDXACB1 | c.1324del p.Q442Sfs*8 | Frame Shift Del (DEL) | VAF 98/391 reads (25%) | called by mutect2, pindel, varscan2
- FOXK1 | c.1129T>C p.S377P | Missense Mutation (SNP) | VAF 560/1364 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GHSR | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 461/633 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GIPC3 | c.3222G>C p.Q1074H | Missense Mutation (SNP) | VAF 112/383 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GP5 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 173/816 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- GPR26 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 215/664 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, varscan2
- GPR62 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 267/524 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HLX | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 804/805 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, varscan2
- HMCN1 | c.3095C>A p.A1032D | Missense Mutation (SNP) | VAF 106/514 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.811); called by muse, varscan2
- KCNN2 | c.280G>A p.G94S (on ENST00000264773; = p.G306S on NM_021614.4) | Missense Mutation (SNP) | VAF 265/416 reads (64%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KLHL34 | c.474G>C p.L158F | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LRRTM3 | c.583A>G p.S195G | Missense Mutation (SNP) | VAF 244/378 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MALL | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 170/534 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); called by muse, varscan2
- MAST2 | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 91/173 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLF1 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 124/501 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- MOB1B | c.567dup p.V190Cfs*8 | Frame Shift Ins (INS) | VAF 132/228 reads (58%) | called by mutect2, varscan2
- MUC19 | c.900T>G p.S300R | Missense Mutation (SNP) | VAF 210/543 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MUC6 | c.5250_5261del p.H1752_S1755del | In Frame Del (DEL) | VAF 303/1749 reads (17%) | called by mutect2, pindel, varscan2
- NBEA | c.6469C>G p.P2157A | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPBWR1 | c.572T>A p.V191D | Missense Mutation (SNP) | VAF 219/439 reads (50%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- NUP188 | c.4044G>C p.Q1348H | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR52N1 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 104/456 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR8J2 | c.734T>G p.M245R | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- OR9A4 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 114/562 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OS9 | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 270/754 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.6020T>C p.V2007A (on ENST00000547103; = p.V1998A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- P2RY2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 424/609 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PCDHGB6 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 296/834 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- PDE4D | c.1636G>A p.E546K (on ENST00000340635 / NM_001104631.2; = p.E410K on NM_006203.4) | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIEZO2 | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 122/365 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLA2R1 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PLAC8L1 | c.22T>G p.F8V | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PLIN1 | c.1151_1155del p.S384Cfs*7 | Frame Shift Del (DEL) | VAF 163/319 reads (51%) | called by mutect2, pindel, varscan2
- PYGO2 | c.940G>C p.A314P | Missense Mutation (SNP) | VAF 226/737 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- REELD1 | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 135/228 reads (59%) | SIFT tolerated (0.74); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RETREG2 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 41/924 reads (4%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2
- RGPD3 | c.4956A>C p.K1652N | Missense Mutation (SNP) | VAF 234/369 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- RHCE | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 93/144 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHD | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RIMS1 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 276/399 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- RNF213 | c.11061A>T p.K3687N | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RORB | c.275A>C p.K92T (on ENST00000396204 / NM_001365023.1; = p.K81T on NM_006914.4) | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- RUNX2 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 196/661 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SCN4A | c.5296C>A p.P1766T | Missense Mutation (SNP) | VAF 195/648 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SERGEF | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHROOM1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 515/783 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SKAP2 | c.786A>C p.E262D | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC17A9 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 790/1194 reads (66%) | SIFT tolerated (0.86); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPATA31A1 | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 221/604 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- STK31 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TAOK3 | c.1622A>G p.Q541R | Missense Mutation (SNP) | VAF 105/447 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TMEM161B | c.659+1G>A p.X220_splice | Splice Site (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- TNIK | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 180/366 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TP53BP1 | c.2972T>C p.L991P | Missense Mutation (SNP) | VAF 213/307 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM9 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 196/804 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSHZ3 | c.2326C>T p.H776Y | Missense Mutation (SNP) | VAF 388/519 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TTLL7 | c.2210T>G p.V737G | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TYW1 | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 100/828 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB16 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 171/565 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZC3H12A | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 428/619 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZMYM6 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 57/196 reads (29%) | called by mutect2, varscan2
- ZNF14 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 159/463 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZNF44 | c.724G>C p.D242H (on ENST00000356109 / NM_001164276.2; = p.D194H on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZNF585A | c.2118A>C p.Q706H (on ENST00000292841 / NM_001288800.2; = p.Q651H on NM_152655.3) | Missense Mutation (SNP) | VAF 311/469 reads (66%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ABCA13 | c.6195C>A p.I2065= | Silent (SNP) | VAF 126/439 reads (29%) | called by muse, mutect2, varscan2
- ABCB4 | c.1206T>G p.S402= | Silent (SNP) | VAF 249/453 reads (55%) | called by muse, mutect2, varscan2
- ADGRL2 | c.1224T>G p.T408= | Silent (SNP) | VAF 81/166 reads (49%) | called by muse, mutect2, varscan2
- CCDC168 | c.15201T>A p.V5067= | Silent (SNP) | VAF 152/327 reads (46%) | called by muse, mutect2, varscan2
- CCDC85A | c.45G>A p.A15= | Silent (SNP) | VAF 209/693 reads (30%) | called by muse, mutect2, varscan2
- CSE1L | c.1989C>T p.V663= | Silent (SNP) | VAF 168/553 reads (30%) | catalogued as rs959173237, COSV53702482; called by muse, mutect2, varscan2
- DNAH1 | c.7149C>A p.G2383= | Silent (SNP) | VAF 98/219 reads (45%) | called by muse, mutect2, varscan2
- DPYS | c.1171A>C p.R391= | Silent (SNP) | VAF 201/201 reads (100%) | catalogued as COSV59826759, COSV59826868, COSV59826998; called by muse, mutect2, varscan2
- DQX1 | c.708C>T p.Y236= | Silent (SNP) | VAF 172/489 reads (35%) | catalogued as rs1291721637; called by muse, mutect2, varscan2
- ERBB4 | c.2271T>G p.T757= | Silent (SNP) | VAF 202/311 reads (65%) | called by muse, mutect2, varscan2
- ERBB4 | c.2148T>G p.T716= | Silent (SNP) | VAF 183/307 reads (60%) | catalogued as COSV53551284, COSV53560427; called by muse, mutect2, varscan2
- GDF7 | c.447C>T p.N149= | Silent (SNP) | VAF 194/668 reads (29%) | catalogued as rs776567882, COSV55348366; called by muse, mutect2, varscan2
- GRIK3 | c.285C>A p.T95= | Silent (SNP) | VAF 106/283 reads (37%) | called by muse, mutect2, varscan2
- HK3 | c.2463C>T p.D821= | Silent (SNP) | VAF 154/1838 reads (8%) | catalogued as rs200491262, COSV99457540; called by muse, mutect2
- HMG20B | c.162C>T p.R54= | Silent (SNP) | VAF 112/319 reads (35%) | catalogued as rs760416634, COSV99503025; called by muse, mutect2, varscan2
- HS3ST3B1 | c.21C>T p.G7= | Silent (SNP) | VAF 147/458 reads (32%) | catalogued as rs914664449; called by muse, varscan2
- IQCN | c.3024C>A p.G1008= | Silent (SNP) | VAF 382/567 reads (67%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.264C>T p.R88= | Silent (SNP) | VAF 242/791 reads (31%) | catalogued as COSV51539621, COSV99289917; called by muse, mutect2, varscan2
- KBTBD7 | c.1470C>T p.N490= | Silent (SNP) | VAF 177/377 reads (47%) | catalogued as rs753184411; called by muse, mutect2, varscan2
- KCNN2 | c.1482T>C p.S494= (on ENST00000264773; = p.S706= on NM_021614.4) | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as COSV53292016; called by muse, mutect2, varscan2
- KCNS1 | c.750G>A p.A250= | Silent (SNP) | VAF 220/1432 reads (15%) | catalogued as COSV60259961; called by muse, mutect2, varscan2
- LAPTM4A | c.108C>T p.Y36= | Silent (SNP) | VAF 103/384 reads (27%) | called by muse, mutect2, varscan2
- LRP1B | c.12099A>G p.A4033= | Silent (SNP) | VAF 57/188 reads (30%) | called by muse, varscan2
- MAGEA10 | c.819A>G p.Q273= | Silent (SNP) | VAF 178/179 reads (99%) | catalogued as COSV54883133, COSV99726601; called by muse, mutect2, varscan2
- MALRD1 | c.2148A>G p.Q716= | Silent (SNP) | VAF 81/246 reads (33%) | called by muse, mutect2, varscan2
- MDN1 | c.13045C>T p.L4349= | Silent (SNP) | VAF 141/455 reads (31%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2304C>T p.N768= | Silent (SNP) | VAF 130/824 reads (16%) | catalogued as rs61752007; called by muse, mutect2, varscan2
- PCDH7 | c.924C>T p.F308= | Silent (SNP) | VAF 205/559 reads (37%) | catalogued as COSV100688131; called by muse, mutect2, varscan2
- PCDHB16 | c.795C>T p.S265= | Silent (SNP) | VAF 432/544 reads (79%) | catalogued as rs1033927810, COSV53357332; called by muse, mutect2, varscan2
- PITPNM1 | c.711C>T p.S237= | Silent (SNP) | VAF 240/816 reads (29%) | called by muse, mutect2, varscan2
- POMC | c.312C>T p.R104= | Silent (SNP) | VAF 483/727 reads (66%) | catalogued as rs1020449183; called by muse, mutect2, varscan2
- ROCK1 | c.3507C>T p.D1169= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV67699804; called by muse, mutect2, varscan2
- SCN3A | c.2403G>T p.G801= | Silent (SNP) | VAF 50/209 reads (24%) | catalogued as COSV51814908; called by muse, mutect2, varscan2
- SLC34A3 | c.576G>A p.S192= | Silent (SNP) | VAF 150/631 reads (24%) | catalogued as rs371056228; called by muse, mutect2, varscan2
- SLC44A5 | c.1296T>G p.A432= | Silent (SNP) | VAF 64/165 reads (39%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2565G>A p.T855= (on ENST00000621492; = p.T821= on NM_025248.3) | Silent (SNP) | VAF 36/575 reads (6%) | catalogued as rs755954061; called by muse, mutect2
- TCF24 | c.159G>A p.A53= | Silent (SNP) | VAF 331/1131 reads (29%) | catalogued as rs1321497816; called by muse, mutect2, varscan2
- THBS4 | c.45C>T p.V15= | Silent (SNP) | VAF 365/582 reads (63%) | called by muse, mutect2, varscan2
- TIE1 | c.1734C>T p.D578= | Silent (SNP) | VAF 497/740 reads (67%) | catalogued as rs1271833051; called by muse, mutect2, varscan2
- TMEM132B | c.2415C>A p.G805= | Silent (SNP) | VAF 302/411 reads (73%) | called by muse, mutect2, varscan2
- TMEM244 | c.40T>C p.L14= | Silent (SNP) | VAF 23/339 reads (7%) | called by muse, mutect2
- TMEM95 | c.207C>T p.H69= | Silent (SNP) | VAF 330/331 reads (100%) | called by muse, mutect2, varscan2
- TPGS2 | c.438G>A p.E146= | Silent (SNP) | VAF 120/120 reads (100%) | called by muse, mutect2, varscan2
- TRIM64B | c.288G>A p.E96= | Silent (SNP) | VAF 32/566 reads (6%) | catalogued as rs1487053473; called by muse, mutect2
- TTC12 | c.1167G>A p.A389= | Silent (SNP) | VAF 182/279 reads (65%) | catalogued as rs1465356557, COSV59096643; called by muse, mutect2, varscan2
- ZBTB20 | c.285C>T p.N95= (on ENST00000474710 / NM_001164342.2; = p.N22= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 162/616 reads (26%) | catalogued as rs149286576; called by muse, mutect2, varscan2
- ZNF169 | c.231C>T p.N77= | Silent (SNP) | VAF 428/553 reads (77%) | catalogued as rs368149871; called by muse, mutect2, varscan2
- GABRB3 | chr15:26773705 T>C | 5'Flank (SNP) | VAF 20/496 reads (4%) | called by muse, mutect2
- MDGA1 | c.*1757G>A | 3'UTR (SNP) | VAF 382/582 reads (66%) | called by muse, mutect2, varscan2
- NOTCH1 | c.*528A>G | 3'UTR (SNP) | VAF 144/572 reads (25%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+556T>G | Intron (SNP) | VAF 335/714 reads (47%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-4787G>T | Intron (SNP) | VAF 197/580 reads (34%) | called by muse, mutect2, varscan2
- SCARF1 | c.*77G>C | 3'UTR (SNP) | VAF 177/556 reads (32%) | called by muse, mutect2, varscan2
